Somatic mutation profile of tumor specimen CUPP-B38V-TTM1-A (aliquot CUPP-B38V-TTM1-A-1-0-D-A82Z-47) from CCG case CUPP-B38V, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, metastatic, NOS; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage III; Age at diagnosis: 77.5 years (28,320 days).
Specimen CUPP-B38V-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d1ba81d-a50a-4422-9ede-5e5eb3e221e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CUPP-B38V-NB1-A (Blood Derived Normal), aliquot CUPP-B38V-NB1-A-1-0-D-A82Z-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5db74ead-a32b-488c-9d70-7cce00e17712

The open-access MAF lists 212 somatic variants for this specimen: 131 protein-altering or splice-affecting, 65 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 65, Intron 8, Frame Shift Del 5, In Frame Del 3, 3'UTR 3, 5'Flank 2, Nonsense Mutation 2, 5'UTR 1, 3'Flank 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BNC2 | c.2663A>G p.H888R | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1563774686; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDH23 | c.6614C>T p.P2205L | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs397517349, CM165018, COSV56452143; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- IRS2 | c.3170G>A p.G1057D | Missense Mutation (SNP) | VAF 24/62 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.61); PolyPhen benign (0.027); catalogued as rs1805097, CM003938; ClinVar: risk factor; called by muse, varscan2
- PAH | c.47_48del p.S16* | Frame Shift Del (DEL) | VAF 19/98 reads (19%) | catalogued as rs62642906; ClinVar: pathogenic; called by pindel, varscan2
- PNPLA6 | c.3088_3091dup p.R1031Qfs*38 (on ENST00000414982 / NM_001166111.2; = p.R983Qfs*38 on NM_006702.5) | Frame Shift Ins (INS) | VAF 8/25 reads (32%) | catalogued as rs606231167; ClinVar: pathogenic; called by mutect2, varscan2
- ABCG8 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs759147053, COSV55396094; called by muse, mutect2, varscan2
- ACSBG1 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as rs777002616; called by muse, mutect2, varscan2
- AKAP8L | c.1824_1826del p.E613del | In Frame Del (DEL) | VAF 5/34 reads (15%) | catalogued as rs907146985; called by mutect2, pindel, varscan2
- ANO3 | c.924A>G p.I308M | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1169601167; called by muse, mutect2, varscan2
- ANO6 | c.2530G>A p.V844I | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.084); catalogued as rs773140175, COSV57659952; called by mutect2, varscan2
- AP3B1 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.65); catalogued as rs140209190; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AQR | c.2054A>G p.D685G | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as rs1387800671; called by muse, mutect2, varscan2
- ATP6V0D2 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs772609602, CM165278; called by mutect2, varscan2
- BCL9L | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs757810846; called by muse, mutect2, varscan2
- C4A | c.2711C>T p.T904M | Missense Mutation (SNP) | VAF 40/347 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.049); catalogued as rs572543424; called by muse, mutect2, varscan2
- C4orf54 | c.1759C>T p.P587S | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1328058819; called by muse, mutect2, varscan2
- CD209 | c.1051G>A p.V351I | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs945126737; called by muse, mutect2, varscan2
- CDH5 | c.1358C>T p.T453I | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.266); catalogued as rs1164820831; called by muse, mutect2, varscan2
- CDKL4 | c.103T>A p.F35I | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772678564; called by muse, mutect2, varscan2
- CHAC1 | c.604G>T p.V202L | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); catalogued as rs556102949, COSV71436040; called by muse, mutect2, varscan2
- CLTA | c.601G>A p.D201N (on ENST00000242285 / NM_007096.4; = p.D171N on NM_001833.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1479278680, COSV54256075; called by muse, mutect2, varscan2
- CNTNAP1 | c.2834G>A p.G945D | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.167); catalogued as rs755797621; called by muse, mutect2, varscan2
- COL6A3 | c.2908C>T p.P970S | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.191); catalogued as rs1226873582; called by muse, mutect2, varscan2
- CRB3 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769244816, COSV57568331; called by muse, mutect2, varscan2
- CSRNP1 | c.523A>G p.I175V | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1414744505; called by muse, mutect2, varscan2
- CTNNB1 | c.1955C>T p.A652V | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs1031583127, COSV62711999; called by muse, mutect2, varscan2
- DCHS1 | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs1475913745; called by muse, mutect2, varscan2
- DCN | c.529A>T p.I177F | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.048); catalogued as rs201430261; ClinVar: benign; called by muse, mutect2, varscan2
- DGKZ | c.271G>C p.V91L | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.015); catalogued as rs1428635019; called by muse, mutect2, varscan2
- DSC2 | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.299); catalogued as rs794728063, CM146195; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DST | c.1414G>A p.E472K (on ENST00000361203 / NM_001374722.1; = p.E146K on NM_001723.6) | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as rs781004024, COSV55008687; called by muse, mutect2, varscan2
- ENOSF1 | c.221_228+10del p.X74_splice | Splice Site (DEL) | VAF 6/49 reads (12%) | catalogued as rs1362542737; called by muse*, varscan2
- EPHA3 | c.1679T>C p.I560T | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs751208279; called by muse, varscan2
- FAM171A2 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs879328636; called by muse, mutect2, varscan2
- FERMT2 | c.317T>C p.M106T | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as rs148043444; called by muse, mutect2, varscan2
- FLG | c.4535C>G p.S1512C | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs199810477; called by muse, mutect2, varscan2
- FLG2 | c.4879A>T p.T1627S | Missense Mutation (SNP) | VAF 56/244 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs747946138; called by muse, mutect2, varscan2
- FLG2 | c.1660T>C p.S554P | Missense Mutation (SNP) | VAF 59/291 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs1387374880; called by muse, mutect2, varscan2
- FUT8 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as rs752511284; called by muse, mutect2, varscan2
- GLB1L2 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs373525902, COSV100335557; called by muse, mutect2, varscan2
- GOLGA8K | c.1469C>T p.T490I | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs756351892, COSV68625057; called by muse, mutect2, varscan2
- GRAMD1C | c.615G>C p.E205D | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.317); catalogued as rs181725618; called by mutect2, varscan2
- HYAL2 | c.1045C>T p.R349W | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs781882193; called by muse, mutect2, varscan2
- JSRP1 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.08); catalogued as rs772166195, COSV55554358; called by mutect2, varscan2
- KIAA0232 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as rs760391354; called by muse, mutect2, varscan2
- KIF17 | c.1844C>T p.P615L | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); catalogued as rs1158816257; called by muse, mutect2, varscan2
- KIF5C | c.2213T>C p.L738S | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs749045025; called by muse, mutect2, varscan2
- LINGO4 | c.82G>A p.G28S | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs779992792; called by muse, mutect2, varscan2
- LMTK2 | c.3506A>G p.H1169R | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs774435216; called by muse, mutect2, varscan2
- MAFA | c.118C>G p.R40G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs139422405; called by mutect2, varscan2
- MED13 | c.4424C>A p.S1475Y | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.185); catalogued as rs199700127, COSV101181291; called by muse, mutect2, varscan2
- MED18 | c.55A>G p.M19V | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.249); catalogued as rs367589689; called by muse, mutect2, varscan2
- MEF2B | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1466163641; called by muse, mutect2, varscan2
- MGAM | c.5360dup p.Y1787* | Nonsense Mutation (INS) | VAF 25/141 reads (18%) | catalogued as rs777914137; called by mutect2, pindel, varscan2
- MLLT6 | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); catalogued as rs780792412; called by muse, mutect2, varscan2
- MUC12 | c.12949G>A p.A4317T (on ENST00000379442; = p.A4174T on NM_001164462.1) | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.66); catalogued as rs149795204; called by muse, mutect2, varscan2
- MYO1D | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs145290255; called by mutect2, varscan2
- NADSYN1 | c.1474C>T p.L492F | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV59812612; called by mutect2, varscan2
- NBEAL2 | c.4210C>T p.R1404C | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs762783367, COSV52758607; called by muse, mutect2, varscan2
- NCAPD3 | c.3916C>G p.P1306A | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758877192; called by muse, mutect2, varscan2
- NOS3 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.068); catalogued as rs754610826, COSV52492050; called by muse, mutect2, varscan2
- NRK | c.4676G>A p.R1559H | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs769426284; called by muse, mutect2, varscan2
- NSD1 | c.1364T>C p.M455T | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.018); catalogued as rs143585233; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- NUBP2 | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs146956965; called by muse, mutect2, varscan2
- NUMA1 | c.3470G>A p.R1157Q | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs139134927; called by muse, mutect2, varscan2
- OR1B1 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.864); catalogued as rs138583280; called by muse, varscan2
- OR2J1 | c.715C>T p.L239F | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758842576; called by muse, mutect2, varscan2
- OSR1 | c.37C>T p.H13Y | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.78); catalogued as rs748946826; called by muse, mutect2, varscan2
- PAPLN | c.766G>A p.E256K (on ENST00000554301; = p.E229K on NM_173462.4) | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs555260071; called by muse, mutect2, varscan2
- PARD3B | c.1097C>T p.S366L | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.342); catalogued as rs765443472; called by muse, mutect2, varscan2
- PARN | c.1785T>G p.D595E | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs200434143; ClinVar: uncertain significance; called by mutect2, varscan2
- PCDHB10 | c.2092T>A p.S698T | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1266066808; called by muse, mutect2, varscan2
- PNN | c.1955G>A p.R652Q | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); catalogued as rs151028611; called by muse, varscan2
- PPP4R4 | c.1947A>T p.E649D | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.429); catalogued as rs758129319; called by muse, mutect2, varscan2
- PRDM1 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs146539196; called by muse, mutect2, varscan2
- PRR22 | c.127A>G p.M43V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375731438; called by muse, mutect2, varscan2
- PSMA5 | c.587A>G p.K196R | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs375404309, COSV54748026; called by muse, mutect2, varscan2
- PTH1R | c.823G>T p.A275S | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as rs754279933; called by muse, mutect2, varscan2
- REV3L | c.3716T>A p.V1239D | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); catalogued as rs371753382; called by muse, mutect2, varscan2
- RHBG | c.908C>T p.T303I | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.31); PolyPhen probably damaging (1); catalogued as rs533810536; called by muse, mutect2, varscan2
- RIBC2 | c.322A>C p.K108Q | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.139); catalogued as rs766500558; called by muse, mutect2, varscan2
- S1PR3 | c.38G>C p.R13P | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs201961912; called by muse, mutect2, varscan2
- SAMSN1 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs776302586; called by muse, varscan2
- SHD | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745597869; called by muse, mutect2, varscan2
- SLAMF6 | c.370C>A p.L124M | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1487656914; called by muse, mutect2, varscan2
- SLC27A4 | c.1560G>C p.E520D | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374740669; called by muse, mutect2, varscan2
- SLC4A5 | c.779G>T p.R260L | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.795); catalogued as rs1437443045; called by muse, mutect2, varscan2
- SLC6A17 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs149884117; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMR3A | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1016313924, COSV99895887; called by mutect2, varscan2
- SNX33 | c.229T>A p.S77T | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.202); catalogued as rs774979843; called by muse, mutect2, varscan2
- SNX33 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as rs762452142; called by muse, mutect2, varscan2
- SOCS7 | c.461C>G p.P154R | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.107); catalogued as rs760910480; called by muse, mutect2, varscan2
- SPAG17 | c.5291A>C p.Q1764P | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1234656591; called by muse, mutect2, varscan2
- SPTLC1 | c.929C>G p.A310G | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as rs768841574, CM126941; ClinVar: uncertain significance; called by mutect2, varscan2
- SSC5D | c.556C>A p.P186T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as rs888467688; called by muse, varscan2
- SUSD2 | c.1319A>G p.N440S | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs775608609; called by muse, mutect2, varscan2
- SUSD5 | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs543801064, COSV58878765; called by muse, mutect2, varscan2
- TCF20 | c.5843C>G p.A1948G | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as rs758164737, COSV59488717; called by muse, mutect2, varscan2
- THAP11 | c.536C>T p.T179I | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1239022325; called by muse, mutect2, varscan2
- TMEM151A | c.737A>G p.N246S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.198); catalogued as rs762116267; called by mutect2, varscan2
- TMEM252 | c.341C>A p.A114E | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.148); catalogued as rs1224642118; called by muse, mutect2, varscan2
- TRIM5 | c.895G>A p.V299I | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs150799809; called by muse, mutect2, varscan2
- TUBB8B | c.1143_1165del p.S382Qfs*16 | Frame Shift Del (DEL) | VAF 28/128 reads (22%) | catalogued as rs1255082527; called by pindel, varscan2
- TUBGCP2 | c.2390G>A p.R797Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs146959915; called by muse, mutect2, varscan2
- UNC119 | c.169A>T p.K57* | Nonsense Mutation (SNP) | VAF 17/61 reads (28%) | catalogued as rs267607166, CM005432; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USH2A | c.2296T>C p.C766R | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368687374, CM140484; called by muse, mutect2, varscan2
- VWA8 | c.3998A>G p.H1333R | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as rs1419958974; called by muse, mutect2, varscan2
- WIPF2 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs1465801704, COSV60276495; called by muse, mutect2, varscan2
- ZBTB8A | c.1253C>G p.A418G | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs704886; called by muse, mutect2, varscan2
- ZMIZ1 | c.1784C>T p.T595M | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs746314274, COSV57893500; called by muse, mutect2, varscan2
- ZNF324B | c.1633T>A p.*545Rext*36 | Nonstop Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as rs780035277; called by muse, mutect2, varscan2
- ZNF844 | c.1126C>G p.P376A | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as rs925307490; called by muse, mutect2, varscan2
- APOL3 | c.1019T>C p.L340P (on ENST00000349314 / NM_145640.2; = p.L269P on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- ASPHD2 | c.403A>C p.K135Q | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- EPC2 | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EXOC8 | c.979_984del p.E327_E328del | In Frame Del (DEL) | VAF 32/153 reads (21%) | called by mutect2, pindel, varscan2
- FER1L5 | c.4534C>G p.P1512A (on ENST00000623019; = p.P1485A on NM_001293083.2) | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSTL4 | c.1941G>A p.M647I | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GTF2F1 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ITPR2 | c.2500A>G p.T834A | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYH11 | c.5002A>G p.R1668G | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- NBEAL2 | c.7195_7197del p.F2399del | In Frame Del (DEL) | VAF 26/110 reads (24%) | called by mutect2, pindel, varscan2
- OR4Q3 | c.484T>C p.F162L | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- OR52E5 | c.22_23del p.Q8Vfs*46 | Frame Shift Del (DEL) | VAF 14/92 reads (15%) | called by pindel, varscan2
- OR8I2 | c.497_524delinsGGCGTTCTGTGATTCCGGCATCAATC p.L166Wfs*13 | Frame Shift Del (DEL) | VAF 14/130 reads (11%) | called by muse*, pindel, varscan2*
- PHLPP1 | c.1061C>A p.P354H | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- SETD3 | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, varscan2
- SLC47A2 | c.638A>G p.Q213R | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- TBC1D16 | c.278_284delinsTGGGAG p.E93Vfs*42 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | called by pindel, varscan2*
- TCTN1 | c.995C>A p.T332K (on ENST00000551590 / NM_001173975.3; = p.T318K on NM_024549.6) | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- TSPAN32 | c.160T>C p.Y54H | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- AC098582.1 | c.3082C>A p.R1028= | Silent (SNP) | VAF 25/110 reads (23%) | catalogued as rs145277878; called by muse, mutect2, varscan2
- ANKK1 | c.1998G>A p.A666= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as rs189187004; called by muse, mutect2, varscan2
- ANKRD11 | c.5820C>T p.S1940= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as rs368770538; called by muse, mutect2, varscan2
- API5 | c.246A>G p.A82= | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as rs202237645; called by muse, mutect2, varscan2
- ARHGAP45 | c.3018G>A p.E1006= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as rs749082374; called by muse, mutect2, varscan2
- ASB16 | c.882C>T p.N294= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs528022197; called by mutect2, varscan2
- BCAN | c.2517G>A p.V839= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as rs1290833768; called by muse, mutect2, varscan2
- BRD7 | c.1950A>G p.G650= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as rs757330761; called by muse, mutect2, varscan2
- C3orf80 | c.414C>T p.D138= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs1022575775; called by muse, mutect2, varscan2
- CACNA1H | c.4062C>T p.S1354= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs376236175, COSV61998039; ClinVar: likely benign; called by muse, mutect2, varscan2
- CAMK2G | c.534A>T p.P178= | Silent (SNP) | VAF 20/136 reads (15%) | catalogued as rs138831885; called by muse, mutect2, varscan2
- CENPM | c.474C>T p.P158= | Silent (SNP) | VAF 30/97 reads (31%) | catalogued as rs569652175, COSV53244894; called by muse, mutect2, varscan2
- CEP250 | c.1875G>A p.E625= | Silent (SNP) | VAF 24/128 reads (19%) | called by muse, mutect2, varscan2
- CHTF8 | c.57G>A p.L19= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs1440470436; called by muse, mutect2, varscan2
- CSF2RB | c.321C>T p.D107= | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as rs573268853; called by muse, mutect2, varscan2
- DBH | c.756C>T p.I252= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as rs771304952; called by muse, mutect2, varscan2
- DHX38 | c.1671G>A p.T557= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as rs759341369; called by muse, mutect2, varscan2
- ECPAS | c.5100C>T p.N1700= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as rs772982587, COSV99398850; called by muse, mutect2, varscan2
- ESYT1 | c.2001G>A p.G667= | Silent (SNP) | VAF 18/118 reads (15%) | catalogued as rs1160202334; called by muse, mutect2, varscan2
- EVI5 | c.93C>T p.L31= | Silent (SNP) | VAF 20/140 reads (14%) | catalogued as rs377436686; called by muse, mutect2, varscan2
- FAM160A2 | c.2418G>A p.K806= (on ENST00000449352 / NM_001098794.2; = p.K820= on NM_032127.4) | Silent (SNP) | VAF 36/103 reads (35%) | catalogued as rs762234135; called by muse, mutect2, varscan2
- FRY | c.4902G>A p.R1634= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as rs199764183; called by muse, mutect2, varscan2
- GABRD | c.1320G>A p.A440= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as rs376039954; called by muse, mutect2, varscan2
- GADD45GIP1 | c.18A>G p.R6= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs781042479; called by muse, mutect2, varscan2
- GATAD1 | c.408A>T p.I136= | Silent (SNP) | VAF 27/128 reads (21%) | catalogued as rs1407415648; called by muse, mutect2, varscan2
- GPRIN3 | c.2160T>C p.H720= | Silent (SNP) | VAF 28/133 reads (21%) | catalogued as rs751993090, COSV60885124; called by muse, mutect2, varscan2
- GPSM1 | c.804C>T p.A268= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs150933466; called by muse, mutect2, varscan2
- GRTP1 | c.432T>C p.Y144= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs370119172; called by muse, mutect2, varscan2
- H3C8 | c.408G>A p.A136= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as rs771252482, COSV59953107, COSV59953470; called by muse, mutect2, varscan2
- HASPIN | c.2028C>T p.I676= | Silent (SNP) | VAF 50/145 reads (34%) | catalogued as rs149953458; called by muse, mutect2, varscan2
- HCN2 | c.2013G>A p.L671= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs372314277; called by muse, mutect2, varscan2
- KATNB1 | c.492G>A p.S164= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as rs140767916; called by muse, mutect2, varscan2
- KIF26B | c.4650G>A p.P1550= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as rs566898509, COSV63637185; called by muse, mutect2, varscan2
- KLHL36 | c.471C>T p.I157= | Silent (SNP) | VAF 26/106 reads (25%) | catalogued as rs12921630; called by muse, varscan2
- LRPAP1 | c.336A>T p.I112= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as COSV56346396; called by muse, varscan2
- MAP1S | c.1887C>T p.A629= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs116850611; called by muse, mutect2, varscan2
- MED12L | c.69C>T p.D23= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs750149170; called by muse, mutect2, varscan2
- MFSD4A | c.558T>C p.H186= | Silent (SNP) | VAF 37/134 reads (28%) | called by muse, mutect2, varscan2
- MOGAT1 | c.657C>T p.A219= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as rs746838155, COSV101485115; called by muse, mutect2, varscan2
- MUC12 | c.9645T>A p.V3215= (on ENST00000379442; = p.V3072= on NM_001164462.1) | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs147467999; called by mutect2, varscan2
- MUC5AC | c.6039C>T p.D2013= | Silent (SNP) | VAF 21/122 reads (17%) | catalogued as rs1423716275; called by muse, mutect2, varscan2
- MYH6 | c.2841C>T p.D947= | Silent (SNP) | VAF 44/159 reads (28%) | catalogued as rs140305424; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYOF | c.252G>A p.A84= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as rs375432077; called by muse, mutect2, varscan2
- NPEPL1 | c.852C>T p.C284= | Silent (SNP) | VAF 30/125 reads (24%) | catalogued as rs549684768; called by muse, varscan2
- PALM3 | c.1332A>G p.G444= (on ENST00000340790; = p.G459= on NM_001145028.2) | Silent (SNP) | VAF 43/141 reads (30%) | called by muse, mutect2, varscan2
- PKD1 | c.5070C>T p.A1690= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as rs183090717, COSV99238614; called by muse, varscan2
- PLB1 | c.3747C>T p.N1249= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as rs147469892; called by muse, mutect2, varscan2
- POMT2 | c.936C>T p.D312= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as rs186690580; called by muse, mutect2, varscan2
- PPP2R2A | c.1254A>G p.K418= | Silent (SNP) | VAF 29/148 reads (20%) | catalogued as rs1039033551; called by muse, mutect2, varscan2
- PRELID1 | c.33C>T p.L11= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV57462986; called by muse, mutect2, varscan2
- PRKDC | c.99A>G p.Q33= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs368029332; called by muse, mutect2, varscan2
- PTPN5 | c.1257C>T p.Y419= | Silent (SNP) | VAF 31/144 reads (22%) | catalogued as rs770632314, COSV62129191; called by muse, mutect2, varscan2
- PUS1 | c.615G>T p.L205= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as COSV59035421; called by muse, mutect2, varscan2
- RAB40C | c.366C>T p.I122= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs377620108; called by mutect2, varscan2
- RAD17 | c.1188C>G p.L396= (on ENST00000380774 / NM_133339.2; = p.L385= on NM_002873.1) | Silent (SNP) | VAF 17/95 reads (18%) | called by muse, mutect2, varscan2
- RDX | c.1731C>T p.I577= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as rs146031062; called by mutect2, varscan2
- RYR3 | c.1743C>T p.I581= | Silent (SNP) | VAF 25/143 reads (17%) | catalogued as rs762956231; called by muse, mutect2, varscan2
- SACS | c.5157C>T p.C1719= | Silent (SNP) | VAF 26/155 reads (17%) | catalogued as rs1303199553; called by muse, mutect2, varscan2
- SMARCA2 | c.753A>G p.Q251= | Silent (SNP) | VAF 68/286 reads (24%) | catalogued as rs371645507; called by muse, varscan2
- SORBS1 | c.678C>T p.R226= (on ENST00000361941 / NM_001034954.2; = p.R194= on NM_015385.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs764367722; called by muse, mutect2, varscan2
- UCN2 | c.327C>T p.V109= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as rs762599762; called by muse, mutect2, varscan2
- UNC5A | c.1350C>T p.L450= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as rs140804550; called by muse, mutect2, varscan2
- USP17L17 | c.75C>A p.P25= | Silent (SNP) | VAF 48/516 reads (9%) | catalogued as rs780399365; called by muse, mutect2, varscan2
- WDR90 | c.2841C>T p.A947= | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as rs554240383; called by muse, mutect2, varscan2
- ZFPM1 | c.993C>G p.T331= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as rs1400395056; called by muse, mutect2, varscan2
- AC109583.1 | c.-1319+432A>G | Intron (SNP) | VAF 25/75 reads (33%) | catalogued as rs545564380; called by muse, mutect2, varscan2
- AL669831.3 | chr1:601515 T>C | 5'Flank (SNP) | VAF 29/224 reads (13%) | catalogued as rs78713263; called by muse, varscan2
- ARHGAP22 | c.989-118G>A | Intron (SNP) | VAF 23/93 reads (25%) | catalogued as rs767277238; called by muse, mutect2, varscan2
- C15orf54 | n.572C>T | RNA (SNP) | VAF 16/134 reads (12%) | catalogued as rs752308525; called by mutect2, varscan2
- CLDN16 | c.-46_-45delinsC | 5'UTR (DEL) | VAF 14/173 reads (8%) | catalogued as rs386669518; called by pindel, varscan2*
- FKTN | chr9:105644724 C>A | 3'Flank (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- HEY1 | c.331+353_331+388delinsGGTATACGGGATTTTAAAAAAAAGGTGC | Intron (DEL) | VAF 25/162 reads (15%) | called by pindel, varscan2*
- KDM8 | c.-32+529G>A | Intron (SNP) | VAF 24/91 reads (26%) | catalogued as rs1031352370; called by muse, mutect2, varscan2
- LILRB5 | c.1630-78_1630-48delinsGTGAGTCCTTTCCTCTCCAGGCCCCCAGGCC | Intron (ONP) | VAF 8/68 reads (12%) | called by mutect2*, pindel, varscan2*
- MIER2 | c.*2388G>C | 3'UTR (SNP) | VAF 63/270 reads (23%) | catalogued as rs553736948; called by muse, varscan2
- NTNG2 | c.*877G>A | 3'UTR (SNP) | VAF 23/84 reads (27%) | catalogued as rs1003927570; called by muse, mutect2, varscan2
- RHBDL1 | c.*158dup | 3'UTR (INS) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- SP140L | c.1313+129G>A | Intron (SNP) | VAF 23/108 reads (21%) | catalogued as rs995104903; called by muse, mutect2, varscan2
- SYCE1 | chr10:133568233 del GTCCTCCTC | 5'Flank (DEL) | VAF 12/46 reads (26%) | catalogued as rs780337941; called by mutect2, varscan2
- TTYH2 | c.129+1995_129+2030delinsGGTAAGTTCCCCTGTTGTGACCACAGGTCTCTCCTG | Intron (ONP) | VAF 24/112 reads (21%) | called by pindel, varscan2*
- ZBP1 | c.875-198C>T | Intron (SNP) | VAF 25/82 reads (30%) | catalogued as rs544912730; called by muse, mutect2, varscan2
